Gene-level copy-number profile of tumor specimen C3L-02615-02 (profiled together with C3L-02615-03, C3L-02615-04, C3L-02615-05) from CPTAC case C3L-02615, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 80.6 years (29,454 days).
Specimen C3L-02615-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d2516086-8860-4501-b100-b20af00748d7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02615-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/e903b53d-1c88-40f9-8e0a-28ecd3716ef5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 515; copy number 1: 47; copy number 2: 6,446; copy number 3: 19,434; copy number 4: 19,021; copy number 5: 12,264; copy number 6: 548; copy number 7: 599; copy number 8: 31.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:49,960,249–49,969,625, 2 genes: DEFB114, DEFB113.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 630 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–257,082, 8 genes, copy number 7: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA.
- chr5:269,858–271,516, 1 gene, copy number 7: AC021087.1.
- chr5:4,012,708–6,833,120, 40 genes, copy number 7: AC025773.1, AC025187.1, LINC02063, AC106799.3, AC106799.2, AC106799.1, AC010634.1, LINC02114, AC026719.1, AC026415.1, AC010451.3, AC010451.1, LINC01020, AC010451.2, LINC02121, RN7SKP73, CTD-2297D10.2, ADAMTS16, AC022424.1, ALG3P1, AC091978.1, MTCO1P30, MTCO2P30, MTCO1P31, ICE1, AC010266.2, AC010266.1, AC026797.1, HMGB3P3, LINC02145, MED10, UBE2QL1, AC027334.1, LINC01018, NSUN2, SRD5A1, LINC02102, TENT4A, LINC02236, AC122710.2.
- chr5:6,848,127–6,888,087, 2 genes, copy number 7: RN7SKP79, AC122710.1.
- chr5:7,287,924–11,904,446, 98 genes, copy number 7 (broad region; genes not listed).
- chr5:12,553,890–45,895,970, 445 genes, copy number 7 (broad region; genes not listed).
- chr8:18,055,992–18,097,644, 3 genes, copy number 7: ASAH1, AC124242.1, AC124242.2.
- chr8:54,152,807–54,192,035, 2 genes, copy number 7: RNU6ATAC32P, AC060764.1.
- chr17:4,771,884–5,078,113, 31 genes, copy number 8: TM4SF5, VMO1, AC233723.2, GLTPD2, PSMB6, AC233723.1, PLD2, MINK1, ATP6V0CP1, RN7SL784P, CHRNE, C17orf107, GP1BA, SLC25A11, RNF167, PFN1, ENO3, SPAG7, CAMTA2, AC004771.3, MIR6864, MIR6865, AC004771.1, AC004771.4, AC004771.2, INCA1, KIF1C, KIF1C-AS1, SLC52A1, AC012146.1, AC012146.2.

Autosomal genes at a single copy (total copy number 1): 47. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
